Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2690, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2690-01A (Primary Tumor).

[page 1 of 2]
TCGA-AF-2690

SPECIMEN

- A. Left ovary
- B. Rectum and sigmoid

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectal cancer.

FROZEN SECTION DIAGNOSIS

A - Benign ovarian cystic mass, favor serous cyst adenoma.

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "left ovary" and consists of a cystic ovary with attached fallopian tube segment. The fimbriated portion of fallopian tube measures 3.5 cm in length and 0.5 cm in diameter. The serosal surface and lumen are unremarkable. The subjacent intact cystic ovary measures 4 x 4 x 3.1 cm. The entire specimen weighs 31 grams. The outer surface of the cystic mass is smooth and glistening. Upon opening, there is 1 major loculation and several smaller ones. They are all filled with clear serous fluid. All cyst linings are smooth, tan and glistening. Representative sections of the cyst wall are submitted for frozen section in one block. Additional sections are submitted in three blocks following fixation.

B. Received fresh subsequently fixed in formalin labeled "rectum and sigmoid. The specimen consists of a 33 cm long portion of colon which is partially covered with skin at one end. The opposite end is stapled. The ends are inked. The specimen is predominantly covered with abundant yellow lobular fat on the serosa. Specimen is opened to show pink tan smooth glistening mucosa. There is a large mass toward the distal ends measuring 4.7 x 4.5 x 1.0 cm. This has an ulcerated center with rolled borders and comes within 2.5 cm. of the pectinate line (4.5 cm. of the distal margin). The cut surface of the tumor shows invasion through the

GROSS DESCRIPTION

muscularis propria and coming within 0.5 cm. of the radial margin. The remainder of the mucosa is pink tan smooth glistening with normal to abundant folds having an average circumference of 4.5 cm. Diverticula are grossly identified with no submucosal abscesses or perforations present. Lymph nodes are grossly identified. Representative sections of the specimen are submitted as follows.

BLOCK SUMMARY: 1 - representative luminal margins; 2 through 4 - representative section of tumor which includes tumor to normal and tumor to radial margins; 5 - representative section of pectinate

[page 2 of 2]
[REDACTED]

line; 6 - representative section of normal colon with diverticula; 7
- 11 whole lymph nodes. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A. This ovarian cyst has mostly attenuated, flattened epithelium. In one focus, however, there is a recognizable monolayer of benign-appearing mucinous columnar epithelium of endocervical type. The lesion, therefore, is consistent with a mucinous cystadenoma. The fallopian tube is without significant pathology.

B. The rectum contains an ulcerated, moderately differentiated adenocarcinoma. Please see the template below.

Histologic type: Infiltrating adenocarcinoma.

Histologic grade: Moderately differentiated.

Primary tumor (pT): The tumor extends well into the pericolic fat, pT3c/d.

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative for tumor.

Distance of tumor from closest margin: The tumor is 4.5 cm. from

MICROSCOPIC DESCRIPTION

the distal margin.

Vascular invasion: Rare lymphatic invasion present.

Regional lymph nodes (pN): Metastatic adenocarcinoma is present to three of twenty-four regional lymph nodes, pN2.

Non-lymph node pericolic tumor: Three foci of non-lymph node pericolic soft tissue metastasis are noted.

Distant metastasis (pM): Cannot be assessed.

Other findings: Diverticulosis.

14, 4, 5

DIAGNOSIS

A. Left ovary, left salpingo-oophorectomy - Ovary with mucinous cystadenoma. Attached fallopian tube, no significant pathology.

B. Rectum and sigmoid, resection - Infiltrating moderately differentiated adenocarcinoma of the rectum, extending into pericolic soft tissue. All margins are negative for tumor, but metastatic disease is present to three of twenty-four regional lymph nodes. Non-lymph node pericolic tumor is also noted.

Diverticulosis also noted.

[REDACTED]

Source: NCI Genomic Data Commons file 826655e9-27c6-48a8-8069-a6368d62405c (TCGA-AF-2690.809685E2-9CB6-4C0D-9912-44E0014E9411.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).